Somatic mutation profile of tumor specimen HCM-BROD-0035-C49-06A (aliquot HCM-BROD-0035-C49-06A-21D-A79L-36) from HCMI case HCM-BROD-0035-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Bone, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 9.8 years (3,585 days).
Specimen HCM-BROD-0035-C49-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51c51514-10ad-481d-90ef-de33f8b0a6ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0035-C49-10A (Blood Derived Normal), aliquot HCM-BROD-0035-C49-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/579dd712-17de-4503-976a-cc10a6c86164

The open-access MAF lists 63 somatic variants for this specimen: 43 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 18, Frame Shift Del 5, Intron 2, In Frame Del 2, Nonsense Mutation 2, Frame Shift Ins 2, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL12A1 | c.1253T>A p.I418K | Missense Mutation (SNP) | VAF 133/284 reads (47%) | SIFT tolerated (0.92); PolyPhen benign (0.009); catalogued as rs745309460; called by muse, mutect2, varscan2
- FAAH2 | c.1079G>A p.W360* | Nonsense Mutation (SNP) | VAF 10/222 reads (5%) | catalogued as COSV66506526; called by muse, mutect2
- GLRA3 | c.407A>G p.E136G | Missense Mutation (SNP) | VAF 12/360 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV56872836; called by muse, mutect2
- OR2I1P | c.425C>G p.T142R | Missense Mutation (SNP) | VAF 26/789 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs1260253692; called by muse, mutect2
- PCYOX1 | c.1291A>C p.K431Q | Missense Mutation (SNP) | VAF 35/457 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as rs1298641039; called by muse, mutect2
- POTEC | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 58/562 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.993); catalogued as rs756029134, COSV100743746; called by muse, mutect2
- USH2A | c.1618del p.Q540Rfs*51 | Frame Shift Del (DEL) | VAF 87/374 reads (23%) | catalogued as CM155344; called by mutect2, pindel, varscan2
- VPS8 | c.926A>G p.D309G (on ENST00000625842 / NM_001349294.1; = p.D307G on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/386 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.787); catalogued as rs752682918; called by muse, mutect2, varscan2
- ABCA5 | c.374A>C p.N125T | Missense Mutation (SNP) | VAF 28/404 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- ADGRF1 | c.2057T>C p.I686T | Missense Mutation (SNP) | VAF 13/362 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2
- AKAP9 | c.9429A>G p.Q3143= (on ENST00000359028; = p.Q3119= on NM_005751.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 15/194 reads (8%) | called by muse, mutect2
- BCHE | c.1385T>A p.M462K | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- C1QL1 | c.260dup p.G88Rfs*14 | Frame Shift Ins (INS) | VAF 162/761 reads (21%) | called by mutect2, pindel, varscan2
- GABRA4 | c.688A>T p.T230S | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); called by muse, mutect2
- GSR | c.1539_1544del p.S514_S515del | In Frame Del (DEL) | VAF 153/324 reads (47%) | called by mutect2, pindel, varscan2
- HLCS | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 32/1210 reads (3%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2
- INPP5K | c.383A>G p.N128S | Missense Mutation (SNP) | VAF 114/279 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1755 | c.2123A>G p.E708G | Missense Mutation (SNP) | VAF 28/552 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2
- LIN9 | c.509del p.K170Rfs*33 (on ENST00000366808 / NM_001270410.2; = p.K115Rfs*33 on NM_173083.3 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 40/311 reads (13%) | called by mutect2, pindel, varscan2
- MARCHF7 | c.1201A>T p.R401W | Missense Mutation (SNP) | VAF 59/349 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NF1 | c.4101_4102insC p.Y1369Ifs*11 (on ENST00000358273 / NM_001042492.3; = p.Y1369Ifs*5 on NM_000267.3) | Frame Shift Ins (INS) | VAF 47/293 reads (16%) | called by mutect2, pindel, varscan2
- NIN | c.4606G>T p.E1536* (on ENST00000382041 / NM_182946.1; = p.E823* on NM_016350.4) | Nonsense Mutation (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- OR4C5 | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 98/401 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PANX3 | c.653T>C p.I218T | Missense Mutation (SNP) | VAF 26/570 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2
- PIKFYVE | c.6124A>G p.T2042A | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRDM5 | c.845A>C p.H282P | Missense Mutation (SNP) | VAF 129/312 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PROX1 | c.1085_1086del p.Q362Rfs*72 | Frame Shift Del (DEL) | VAF 61/435 reads (14%) | called by mutect2, pindel, varscan2
- PTP4A3 | c.335C>A p.P112Q | Missense Mutation (SNP) | VAF 80/537 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF17 | c.3892C>A p.P1298T | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RUBCN | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 164/417 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SCG3 | c.1376A>G p.E459G | Missense Mutation (SNP) | VAF 20/427 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); called by muse, mutect2
- SCN8A | c.809T>C p.L270P | Missense Mutation (SNP) | VAF 111/539 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SDK1 | c.4280C>A p.T1427N | Missense Mutation (SNP) | VAF 98/2272 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2
- SIRPB2 | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 164/383 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC25A1 | c.841_858del p.P281_V286del | In Frame Del (DEL) | VAF 36/410 reads (9%) | called by mutect2, pindel
- SNX17 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2
- SOCS2 | c.361A>C p.S121R | Missense Mutation (SNP) | VAF 24/416 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- STPG4 | c.652del p.T218Lfs*2 | Frame Shift Del (DEL) | VAF 29/270 reads (11%) | called by mutect2, pindel, varscan2
- TAT | c.1168G>C p.V390L | Missense Mutation (SNP) | VAF 46/413 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- TRAV9-1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 41/537 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TSPOAP1 | c.1833G>T p.E611D | Missense Mutation (SNP) | VAF 59/433 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- USP9X | c.1310C>G p.A437G | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- ZBTB45 | c.511_520del p.R171Afs*149 | Frame Shift Del (DEL) | VAF 102/651 reads (16%) | called by mutect2, pindel, varscan2
- ALMS1 | c.1992A>G p.V664= | Silent (SNP) | VAF 51/402 reads (13%) | catalogued as rs894774935; ClinVar: likely benign; called by muse, mutect2, varscan2
- DEFB104B | c.42C>T p.L14= | Silent (SNP) | VAF 46/281 reads (16%) | catalogued as rs1447615437; called by muse, mutect2, varscan2
- DENND4C | c.4284T>C p.A1428= (on ENST00000434457 / NM_001330640.2; = p.A1379= on NM_017925.7) | Silent (SNP) | VAF 111/276 reads (40%) | called by muse, mutect2, varscan2
- IGSF9 | c.93C>T p.G31= | Silent (SNP) | VAF 306/658 reads (47%) | called by muse, mutect2, varscan2
- IL10RA | c.675C>A p.S225= | Silent (SNP) | VAF 45/200 reads (23%) | called by muse, mutect2, varscan2
- IRAK2 | c.393G>A p.Q131= | Silent (SNP) | VAF 56/345 reads (16%) | called by muse, mutect2, varscan2
- MPP5 | c.1110T>C p.G370= | Silent (SNP) | VAF 16/396 reads (4%) | called by muse, mutect2
- NBEAL1 | c.7662T>C p.V2554= | Silent (SNP) | VAF 51/307 reads (17%) | called by muse, mutect2, varscan2
- NOP56 | c.171C>T p.S57= | Silent (SNP) | VAF 512/929 reads (55%) | called by muse, mutect2, varscan2
- POM121 | c.147G>A p.V49= | Silent (SNP) | VAF 135/877 reads (15%) | called by muse, mutect2, varscan2
- RNF175 | c.498T>C p.N166= | Silent (SNP) | VAF 13/231 reads (6%) | called by muse, mutect2
- SALL3 | c.2832C>A p.A944= | Silent (SNP) | VAF 346/780 reads (44%) | called by muse, mutect2, varscan2
- SETD2 | c.1839G>A p.G613= | Silent (SNP) | VAF 91/233 reads (39%) | called by muse, mutect2, varscan2
- SH3TC1 | c.1230C>T p.S410= | Silent (SNP) | VAF 110/446 reads (25%) | catalogued as rs376361208; called by muse, varscan2
- SMIM40 | c.42G>C p.L14= | Silent (SNP) | VAF 102/417 reads (24%) | called by muse, mutect2, varscan2
- SPRN | c.258C>T p.G86= | Silent (SNP) | VAF 60/771 reads (8%) | called by muse, mutect2
- TOM1 | c.336C>T p.I112= | Silent (SNP) | VAF 31/570 reads (5%) | catalogued as rs774932722; called by muse, mutect2
- ZMAT5 | c.253C>T p.L85= | Silent (SNP) | VAF 38/547 reads (7%) | called by muse, mutect2
- ATP10B | c.470+861G>A | Intron (SNP) | VAF 289/528 reads (55%) | called by muse, mutect2, varscan2
- EPHA6 | c.2784+8221del | Intron (DEL) | VAF 40/204 reads (20%) | called by mutect2, pindel, varscan2
